Gene-level copy-number profile of tumor specimen MP2PRT-PAYXAD-TTR1-A from MP2PRT case MP2PRT-PAYXAD, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.4 years (1,604 days).
Specimen MP2PRT-PAYXAD-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb8b5abd-fb4c-4d0a-a02b-946dfc68ee46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAYXAD-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/18fd2174-0b72-48b7-ad43-778cb9b4b402

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,719; copy number 2: 47,317; copy number 3: 5,215; copy number 4: 411; copy number 5: 496; copy number 6: 40; copy number 10: 37; copy number 12: 111; copy number 13: 30; copy number 16: 6; copy number 20: 24.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 744 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,239,843–174,286,644, 112 genes, copy number 5 (broad region; genes not listed).
- chr3:181,847,526–190,449,876, 183 genes, copy number 5 (broad region; genes not listed).
- chr3:191,425,493–198,123,232, 182 genes, copy number 5–6 (broad region; genes not listed).
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr17:1,241,939–1,900,082, 27 genes, copy number 5: AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1.
- chr17:2,724,411–2,749,504, 3 genes, copy number 5: CCDC92B, MIR1253, hsa-mir-1253.
- chr19:35,666,516–35,946,624, 28 genes, copy number 5: UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3.
- chr19:37,007,857–37,130,368, 1 gene, copy number 10 (within-gene range 2–10): ZNF420.
- chr19:37,075,113–41,137,308, 207 genes, copy number 10–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,712. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
